Gene-level copy-number profile of tumor specimen TCGA-CV-7409-01A from TCGA case TCGA-CV-7409, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 43.5 years (15,888 days).
Specimen TCGA-CV-7409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.373f1213-67d5-4eb4-80d4-536296d4787f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7409-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/403421bd-238e-4c04-80c8-d7ad37cdc32d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 544; copy number 2: 7,904; copy number 3: 27,324; copy number 4: 11,211; copy number 5: 5,790; copy number 6: 4,344; copy number 7: 1,058; copy number 8: 1,602; copy number 10: 14; copy number 11: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CV-7409-01): tumor purity 0.61, ploidy 3.59, whole-genome doublings 2 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,696 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,979,688–46,036,122, 172 genes, copy number 8 (broad region; genes not listed).
- chr2:101,551,592–102,058,190, 5 genes, copy number 10: AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1.
- chr2:189,486,480–200,584,096, 142 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr2:201,377,207–201,895,550, 22 genes, copy number 7 (within-gene range 2–7): TRAK2, STRADB, SCYL2P1, Y_RNA, C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11.
- chr2:202,840,331–203,738,912, 20 genes, copy number 7 (within-gene range 2–7): KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2, ABI2, AC080075.1, RAPH1, AC125238.2, AC125238.1, CD28.
- chr3:95,916,726–96,814,407, 11 genes, copy number 7: AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr3:192,516,831–196,082,096, 97 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr4:159,103,013–159,360,174, 1 gene, copy number 7 (within-gene range 4–7): RAPGEF2.
- chr4:159,375,099–159,401,246, 2 genes, copy number 7: AC074344.1, AC074344.2.
- chr7:87,503,017–89,496,918, 22 genes, copy number 7–10: ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1.
- chr8:64,798,804–145,066,685, 1,257 genes, copy number 7–8 (broad region; genes not listed).
- chr14:67,189,393–67,734,451, 26 genes, copy number 8: FAM71D, SF3B4P1, MPP5, AL135978.1, ATP6V1D, Y_RNA, EIF2S1, PLEK2, MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9.
- chr14:67,735,195–67,735,350, 1 gene, copy number 8: AL049779.3.
- chr20:28,563,850–64,313,132, 918 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
